Somatic mutation profile of tumor specimen C3L-00677-72 (aliquot CPT0071100006) from CPTAC case C3L-00677, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 70.0 years (25,562 days).
Specimen C3L-00677-72: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 029e4dd9-610c-49c2-b513-0b782612b75e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00677-31 (Blood Derived Normal), aliquot CPT0071960002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b441d130-bb6f-4526-8cba-481e3c2a540a

The open-access MAF lists 1,873 somatic variants for this specimen: 1,193 protein-altering or splice-affecting, 479 silent, 201 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,003, Silent 479, Intron 105, Frame Shift Del 60, Nonsense Mutation 60, 3'UTR 31, In Frame Del 22, RNA 20, Splice Region 20, 5'UTR 20, Frame Shift Ins 14, 3'Flank 13.

Variants (750 of 1,873; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD1 | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 180/377 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs886044777, CM950047; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALPL | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.994); catalogued as rs121918011, CM127629, CM138789, CM980062; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRIP1 | c.2119C>T p.R707C | Missense Mutation (SNP) | VAF 70/210 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764803896, CM053141, COSV51995063; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- COL7A1 | c.5047C>T p.R1683* | Nonsense Mutation (SNP) | VAF 48/235 reads (20%) | catalogued as rs760063197, CM056314, COSV60401506; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DDB2 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 50/230 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as rs121434640, CM960485, COSV99921391; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DNMBP | c.811C>T p.R271* | Nonsense Mutation (SNP) | VAF 42/58 reads (72%) | catalogued as rs1564745688, COSV100143016; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ETFA | c.625C>T p.R209* | Nonsense Mutation (SNP) | VAF 135/341 reads (40%) | catalogued as rs199763682, COSV51211999; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LMNA | c.94_96del p.K32del | In Frame Del (DEL) | VAF 135/311 reads (43%) | catalogued as rs60872029; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MMADHC | c.160C>T p.R54* | Nonsense Mutation (SNP) | VAF 25/239 reads (10%) | catalogued as rs118204047, CM081191, COSV57574342; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 292/705 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148808089, CM066924; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PKP2 | c.1951C>T p.R651* | Nonsense Mutation (SNP) | VAF 46/175 reads (26%) | catalogued as rs751288871, CM043057; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 63/103 reads (61%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs121913294, CM074465, CM102472, COSV100911374, COSV64288961, COSV64302184; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RARS2 | c.1282G>A p.G428R | Missense Mutation (SNP) | VAF 120/639 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764875815; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1814+1G>A p.X605_splice | Splice Site (SNP) | VAF 67/189 reads (35%) | hotspot (GDC flag); catalogued as CD952454, CS961682, COSV57294691, COSV57319332; called by muse, mutect2, varscan2
- RYR1 | c.7355G>A p.R2452Q | Missense Mutation (SNP) | VAF 162/491 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs193922815, CM064218, CM091639; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC7A9 | c.997C>T p.R333W | Missense Mutation (SNP) | VAF 109/413 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121908484, CM010449, COSV50088053; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TBX6 | c.704del p.G235Afs*15 | Frame Shift Del (DEL) | VAF 87/218 reads (40%) | catalogued as rs758051786, COSV54222619; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 87/271 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 124/271 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen possibly damaging (0.45); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.69415C>T p.R23139* (on ENST00000591111; = p.R15715* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 38/80 reads (48%) | catalogued as rs794729285, CM1514684; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.12661C>T p.R4221C | Missense Mutation (SNP) | VAF 60/239 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68943091; called by muse, mutect2, varscan2
- ABCA2 | c.2248G>A p.V750M (on ENST00000614293; = p.V720M on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/253 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1209694133; called by muse, mutect2, varscan2
- ABCA7 | c.4681C>T p.R1561* | Nonsense Mutation (SNP) | VAF 37/190 reads (19%) | catalogued as rs768471733, COSV54029163; called by muse, mutect2, varscan2
- ABCA8 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.22); catalogued as rs755088665, COSV52210429, COSV52211116; called by muse, mutect2, varscan2
- ABCB11 | c.3676C>T p.R1226C | Missense Mutation (SNP) | VAF 76/203 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772241929, COSV55591899; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB5 | c.3611G>A p.G1204E (on ENST00000404938 / NM_001163941.2; = p.G759E on NM_178559.6) | Missense Mutation (SNP) | VAF 106/273 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs754168898; called by muse, mutect2, varscan2
- ABCC12 | c.3970G>A p.V1324I | Missense Mutation (SNP) | VAF 69/172 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs1469497491, COSV60912738; called by muse, mutect2, varscan2
- ABCC4 | c.2743C>T p.R915W | Missense Mutation (SNP) | VAF 77/233 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs978321113; called by muse, mutect2, varscan2
- ABHD16B | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 132/509 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.362); catalogued as rs751267422; called by muse, mutect2, varscan2
- ABHD4 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs949135495, COSV99360557; called by muse, mutect2, varscan2
- ABRA | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 186/408 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.258); catalogued as rs145381419, COSV61732723; called by muse, mutect2, varscan2
- ABTB1 | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1377072066, COSV51743124; called by muse, mutect2, varscan2
- ABTB1 | c.1366G>A p.A456T (on ENST00000232744 / NM_172027.3; = p.A314T on NM_032548.3) | Missense Mutation (SNP) | VAF 117/257 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as rs942139411; called by muse, mutect2, varscan2
- AC004922.1 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 101/406 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.398); catalogued as rs370232879; called by muse, mutect2, varscan2
- ACACB | c.6305G>A p.R2102Q | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs368938120, COSV58129524; called by muse, mutect2
- ACAT1 | c.254_256del p.E85del | In Frame Del (DEL) | VAF 46/204 reads (23%) | catalogued as rs866364527; called by pindel, varscan2
- ACTR3B | c.1237G>A p.V413I | Missense Mutation (SNP) | VAF 86/316 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.255); catalogued as rs751597401; called by muse, mutect2, varscan2
- ACVRL1 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 243/434 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774389618, CM060789, COSV66359608; called by muse, mutect2, varscan2
- ADAM22 | c.992+4C>T | Splice Region (SNP) | VAF 62/238 reads (26%) | catalogued as rs199689664; called by muse, mutect2, varscan2
- ADAM23 | c.1666C>T p.R556* | Nonsense Mutation (SNP) | VAF 76/221 reads (34%) | catalogued as rs758588742, COSV52220408; called by muse, mutect2, varscan2
- ADAMTS10 | c.2681C>T p.S894L | Missense Mutation (SNP) | VAF 60/188 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.59); catalogued as COSV54355331; called by muse, mutect2, varscan2
- ADAMTS16 | c.2974G>A p.A992T | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs751536987, COSV56996986; called by muse, mutect2, varscan2
- ADAMTS20 | c.4849G>A p.E1617K | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs760483355; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2284G>A p.V762M | Missense Mutation (SNP) | VAF 141/329 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63206837; called by muse, mutect2, varscan2
- ADAMTSL5 | c.1309G>A p.D437N | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.794); catalogued as rs767610041; called by muse, mutect2, varscan2
- ADAR | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 99/198 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs762695102; called by muse, mutect2, varscan2
- ADARB1 | c.1942G>A p.A648T (on ENST00000360697 / NM_001346687.2; = p.A608T on NM_001112.4) | Missense Mutation (SNP) | VAF 81/174 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs1010081989; called by muse, mutect2, varscan2
- ADCK1 | c.1270G>A p.V424M | Missense Mutation (SNP) | VAF 90/198 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.404); catalogued as rs762239164; called by muse, mutect2, varscan2
- ADCY5 | c.1882C>T p.R628C | Missense Mutation (SNP) | VAF 73/223 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1252252107; called by muse, mutect2, varscan2
- ADCY6 | c.2866G>A p.V956M | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1367267802; called by muse, mutect2, varscan2
- ADCY7 | c.1180G>A p.V394M | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763219848; called by muse, mutect2, varscan2
- ADGRB2 | c.1700G>A p.R567H | Missense Mutation (SNP) | VAF 53/191 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1424298631, COSV57074338, COSV99926649; called by muse, mutect2, varscan2
- ADGRB3 | c.3370C>T p.R1124C | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs896719594, COSV53238070, COSV99487208; called by muse, mutect2, varscan2
- ADGRV1 | c.11827C>T p.R3943W | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762677981, COSV67996847; called by muse, mutect2, varscan2
- ADORA1 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 50/225 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV58810354; called by muse, mutect2, varscan2
- AGFG2 | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as rs778865607, COSV104368550; called by muse, mutect2, varscan2
- AGPS | c.1780G>A p.V594I | Missense Mutation (SNP) | VAF 67/319 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.206); catalogued as rs764836897, COSV51561213; called by muse, mutect2, varscan2
- AHDC1 | c.3628G>A p.E1210K | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs1355731397; called by muse, mutect2, varscan2
- AHDC1 | c.1951G>A p.D651N | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as rs774212366; called by muse, mutect2, varscan2
- AMER3 | c.79G>A p.V27M | Missense Mutation (SNP) | VAF 68/158 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as rs374506642, COSV100365960; called by muse, mutect2, varscan2
- AMHR2 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 137/311 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs767904039, COSV57684903; called by muse, mutect2, varscan2
- ANAPC2 | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1239291007; called by muse, mutect2, varscan2
- ANAPC2 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 106/269 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs769623104, COSV59245547; called by muse, mutect2, varscan2
- ANGPT4 | c.356T>C p.V119A | Missense Mutation (SNP) | VAF 50/217 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs767678821; called by muse, mutect2, varscan2
- ANGPTL2 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 89/192 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as rs1015094610, COSV99402260; called by muse, mutect2, varscan2
- ANK2 | c.9682G>A p.V3228M | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as rs141013157; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD26P1 | n.1845C>T | Splice Region (SNP) | VAF 30/69 reads (43%) | catalogued as rs750662408; called by muse, mutect2, varscan2
- ANKRD27 | c.3098C>T p.P1033L | Missense Mutation (SNP) | VAF 50/308 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs150349860, COSV60132493; called by muse, mutect2, varscan2
- ANKRD30BL | c.615C>T p.C205= | Splice Region (SNP) | VAF 12/34 reads (35%) | catalogued as rs1254657266; called by muse, varscan2
- ANKRD53 | c.1321G>A p.G441S | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.866); catalogued as rs781803085; called by muse, mutect2, varscan2
- ANO9 | c.1127C>T p.T376M | Missense Mutation (SNP) | VAF 18/207 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs1208677558, COSV60452586; called by muse, mutect2
- AP1M2 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1025421977; called by muse, mutect2, varscan2
- AP5S1 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs184260219; called by muse, mutect2
- AP5Z1 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.3); catalogued as rs542054269, COSV62242022; called by muse, mutect2, varscan2
- APBA3 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.056); catalogued as rs1326420109; called by muse, mutect2, varscan2
- APBB3 | c.760C>T p.R254* (on ENST00000357560 / NM_133173.2; = p.R261* on NM_006051.3) | Nonsense Mutation (SNP) | VAF 78/180 reads (43%) | catalogued as rs1200620061; called by muse, varscan2
- APEX2 | c.1411G>A p.G471S | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.957); catalogued as rs1240489736; called by muse, mutect2, varscan2
- APOL3 | c.644C>T p.T215M (on ENST00000349314 / NM_145640.2; = p.T144M on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 96/146 reads (66%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs776498506, COSV62579144; called by muse, mutect2, varscan2
- APOL6 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 102/132 reads (77%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as rs370134377; called by muse, mutect2, varscan2
- AQP2 | c.323C>T p.T108M | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as rs1468828294, CM146787; called by muse, mutect2, varscan2
- ARGFX | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.235); catalogued as rs752404821, COSV57682040; called by muse, mutect2, varscan2
- ARHGAP11B | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 65/183 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368952454; called by muse, mutect2, varscan2
- ARHGAP17 | c.1892G>A p.R631Q (on ENST00000289968 / NM_001006634.3; = p.R553Q on NM_018054.6) | Missense Mutation (SNP) | VAF 80/196 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs200789627; called by muse, mutect2, varscan2
- ARHGAP31 | c.655G>A p.G219S | Missense Mutation (SNP) | VAF 168/406 reads (41%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as rs370881248; called by muse, mutect2, varscan2
- ARHGAP31 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 111/306 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs762629877, COSV51791283; called by muse, mutect2, varscan2
- ARHGAP39 | c.2069C>T p.S690L | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV52775082, COSV99432426; called by muse, mutect2, varscan2
- ARHGAP5 | c.2575C>T p.R859W | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1436635673, COSV61534652; called by muse, mutect2, varscan2
- ARHGEF10 | c.1990C>T p.R664C (on ENST00000398564; = p.R639C on NM_014629.4) | Missense Mutation (SNP) | VAF 23/385 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs751056745, COSV50653571; called by muse, mutect2
- ARHGEF11 | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142608371; called by muse, mutect2, varscan2
- ARHGEF28 | c.1718G>A p.R573H | Missense Mutation (SNP) | VAF 56/210 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs373048783; called by muse, mutect2, varscan2
- ARHGEF40 | c.2312G>A p.R771H | Missense Mutation (SNP) | VAF 61/148 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.642); catalogued as rs761052679; called by muse, mutect2, varscan2
- ARID1A | c.3977del p.P1326Rfs*155 | Frame Shift Del (DEL) | VAF 96/288 reads (33%) | catalogued as COSV61372705; called by mutect2, pindel, varscan2
- ARL4D | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.105); catalogued as COSV60721725; called by muse, mutect2, varscan2
- ARMC10 | c.323C>T p.T108M | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs761785012; called by muse, mutect2, varscan2
- ARNT2 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 89/206 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs755179995, COSV57586671; called by muse, mutect2, varscan2
- ARVCF | c.1252C>T p.R418C | Missense Mutation (SNP) | VAF 63/191 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV54270236; called by muse, mutect2, varscan2
- ASAP3 | c.2573G>A p.R858Q | Missense Mutation (SNP) | VAF 93/230 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.988); catalogued as rs745986617; called by muse, mutect2, varscan2
- ASPG | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 77/155 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs746427452; called by muse, mutect2, varscan2
- ASPM | c.7708T>C p.Y2570H | Missense Mutation (SNP) | VAF 113/227 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.292); catalogued as rs748115962; called by muse, mutect2, varscan2
- ATAD2B | c.1404del p.F468Lfs*9 | Frame Shift Del (DEL) | VAF 89/272 reads (33%) | catalogued as rs866490133; called by mutect2, pindel, varscan2
- ATM | c.9001_9002del p.S3001Ffs*6 | Frame Shift Del (DEL) | VAF 300/640 reads (47%) | catalogued as rs876660022; called by pindel, varscan2
- ATP10A | c.2800G>A p.V934M | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.523); catalogued as rs145756944; called by muse, mutect2
- ATP10B | c.3829G>A p.V1277I | Missense Mutation (SNP) | VAF 67/134 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.147); catalogued as rs757825777, COSV59166719; called by muse, mutect2, varscan2
- ATP11C | c.3052A>G p.T1018A | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100558886; called by muse, mutect2, varscan2
- ATP13A2 | c.3439C>T p.R1147C | Missense Mutation (SNP) | VAF 91/243 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs370421723; called by muse, mutect2, varscan2
- ATP13A3 | c.1870C>T p.R624C | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.416); catalogued as rs375504912; called by muse, mutect2
- ATP1A1 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs765069962; called by muse, mutect2, varscan2
- ATP1A3 | c.257C>T p.P86L (on ENST00000545399 / NM_001256214.2; = p.P73L on NM_152296.5) | Missense Mutation (SNP) | VAF 154/564 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs1161880070, COSV57485078; called by muse, mutect2, varscan2
- ATP2A3 | c.1571G>A p.R524H | Missense Mutation (SNP) | VAF 126/313 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767403905, COSV59233401; called by muse, mutect2, varscan2
- ATP2A3 | c.997G>A p.V333M | Missense Mutation (SNP) | VAF 174/434 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs370176557; called by muse, mutect2, varscan2
- ATP5F1B | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 136/287 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.825); catalogued as rs778911180, COSV51634667; called by muse, mutect2, varscan2
- ATP6V0A4 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 227/853 reads (27%) | catalogued as CM065978, COSV59481268; called by muse, mutect2, varscan2
- ATP6V1F | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 107/375 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); catalogued as rs1466567024, COSV50799955; called by muse, mutect2, varscan2
- ATP6V1FNB | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as rs1328786528; called by muse, mutect2, varscan2
- ATP8B1 | c.3490C>T p.R1164* | Nonsense Mutation (SNP) | VAF 174/467 reads (37%) | catalogued as rs369054652, CM043833; called by muse, mutect2, varscan2
- ATP9A | c.1901C>T p.T634M | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.717); catalogued as rs867360476, COSV58765357; called by muse, mutect2
- ATRX | c.1960C>T p.R654* | Nonsense Mutation (SNP) | VAF 136/357 reads (38%) | catalogued as COSV64870592, COSV64871923; called by muse, mutect2, varscan2
- B4GALNT4 | c.2624G>A p.R875H | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.466); catalogued as rs1312493980; called by muse, mutect2, varscan2
- BAHCC1 | c.2471G>A p.R824H | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as rs782660404; called by muse, mutect2, varscan2
- BCAM | c.1739G>A p.R580H | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.142); catalogued as rs761165322, COSV54302398; ClinVar: likely benign; called by muse, mutect2, varscan2
- BCL11B | c.908C>T p.P303L (on ENST00000357195 / NM_001282237.2; = p.P232L on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs752385859; called by mutect2, varscan2
- BCL6B | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 74/185 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs750978030; called by muse, mutect2, varscan2
- BCL9 | c.2419G>A p.D807N | Missense Mutation (SNP) | VAF 153/363 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs587607792, COSV52340431; called by muse, mutect2, varscan2
- BCORL1 | c.2365C>T p.R789C | Missense Mutation (SNP) | VAF 70/150 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371862075, COSV54409758; called by muse, mutect2, varscan2
- BEST1 | c.1326_1328del p.N442del | In Frame Del (DEL) | VAF 176/412 reads (43%) | catalogued as rs1316030506; called by pindel, varscan2
- BEST2 | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 50/252 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs770731972, COSV104378090; called by muse, varscan2
- BICRA | c.1616C>T p.A539V | Missense Mutation (SNP) | VAF 53/188 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as rs373150892; called by muse, mutect2, varscan2
- BMP7 | c.1243G>A p.V415I | Missense Mutation (SNP) | VAF 245/918 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1463340387; called by muse, mutect2, varscan2
- BORCS6 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 98/244 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as rs762597553; called by muse, varscan2
- BPIFB4 | c.1143C>T p.N381= | Splice Region (SNP) | VAF 45/133 reads (34%) | catalogued as rs542993165; called by muse, mutect2, varscan2
- BSN | c.10828C>T p.R3610* | Nonsense Mutation (SNP) | VAF 44/152 reads (29%) | catalogued as rs1399229458, COSV56518920; called by muse, mutect2, varscan2
- BTBD2 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 100/334 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs756206197, COSV55308214; called by muse, mutect2, varscan2
- BYSL | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs771976157, COSV100027016; called by muse, mutect2, varscan2
- BYSL | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 164/429 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764063989, COSV57827754; called by muse, mutect2, varscan2
- C19orf12 | c.338C>T p.T113M (on ENST00000392278 / NM_001031726.3; = p.T102M on NM_031448.6) | Missense Mutation (SNP) | VAF 127/467 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.176); catalogued as rs139585199; called by muse, mutect2, varscan2
- C1orf116 | c.1465G>A p.V489M | Missense Mutation (SNP) | VAF 88/213 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs150604105; called by muse, mutect2, varscan2
- C4orf45 | c.220G>A p.V74I | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.577); catalogued as rs767803611, COSV71700751; called by muse, mutect2, varscan2
- CABIN1 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 26/400 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs573408065, COSV54089737; called by muse, mutect2
- CACNA1A | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 63/247 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs759782636; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1A | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 95/310 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1365721398, COSV64200218; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1B | c.2995_2997del p.K999del | In Frame Del (DEL) | VAF 125/266 reads (47%) | catalogued as rs1167442485; called by mutect2, pindel, varscan2
- CACNA2D3 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 75/172 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1265001369, COSV55587238; called by muse, mutect2, varscan2
- CACNB1 | c.1487G>A p.R496H | Missense Mutation (SNP) | VAF 108/234 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs776999073; called by muse, mutect2, varscan2
- CAD | c.4771G>A p.A1591T | Missense Mutation (SNP) | VAF 74/203 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1031988936; called by muse, mutect2, varscan2
- CALML4 | c.369_371del p.E123del | In Frame Del (DEL) | VAF 58/154 reads (38%) | catalogued as rs774166047; called by pindel, varscan2
- CAMK4 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1386520704, COSV56677300; called by muse, mutect2, varscan2
- CAPN11 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as rs376701678; called by muse, mutect2, varscan2
- CARD19 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 102/259 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.179); catalogued as rs752611032, COSV64936096; called by muse, mutect2, varscan2
- CARNS1 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs1332659955; called by muse, mutect2, varscan2
- CASP14 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 104/321 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs936540103, COSV55664718; called by muse, mutect2, varscan2
- CAVIN1 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.311); catalogued as COSV63812830; called by muse, mutect2, varscan2
- CBL | c.1495C>T p.R499* | Nonsense Mutation (SNP) | VAF 578/1023 reads (57%) | catalogued as rs778927765, COSV50660744; called by muse, mutect2, varscan2
- CCAR2 | c.1013C>T p.T338M | Missense Mutation (SNP) | VAF 79/226 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.333); catalogued as rs199827847, COSV100414962; called by muse, mutect2, varscan2
- CCDC106 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.773); catalogued as rs759847216; called by muse, mutect2, varscan2
- CCDC15 | c.1159_1160del p.E387Nfs*12 | Frame Shift Del (DEL) | VAF 42/370 reads (11%) | catalogued as rs1385065742; called by mutect2, pindel
- CCDC182 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as rs377448763; called by muse, mutect2, varscan2
- CCDC73 | c.1913del p.N638Ifs*18 | Frame Shift Del (DEL) | VAF 63/163 reads (39%) | catalogued as rs762553129; called by mutect2, varscan2
- CCDC88C | c.1793C>T p.T598M | Missense Mutation (SNP) | VAF 138/354 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs200148068; called by muse, mutect2, varscan2
- CCP110 | c.982C>T p.R328* | Nonsense Mutation (SNP) | VAF 90/231 reads (39%) | catalogued as rs1462705993, COSV66818143; called by muse, mutect2, varscan2
- CD33 | c.109G>A p.V37I | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.241); catalogued as rs771741922; called by muse, mutect2, varscan2
- CD8B | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 86/212 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.06); catalogued as rs774522740; called by muse, mutect2, varscan2
- CDC14B | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781581318; called by muse, mutect2, varscan2
- CDC25B | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 90/260 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs76772959, COSV55659851; called by muse, mutect2, varscan2
- CDC25B | c.491G>A p.R164Q (on ENST00000245960 / NM_021873.3; = p.R150Q on NM_004358.4) | Missense Mutation (SNP) | VAF 31/216 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs538158719; called by muse, mutect2, varscan2
- CDC42BPB | c.1114G>A p.V372M | Missense Mutation (SNP) | VAF 75/149 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1445044341; called by muse, mutect2, varscan2
- CDC42BPG | c.4298G>A p.R1433H | Missense Mutation (SNP) | VAF 69/249 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368803975; called by muse, mutect2, varscan2
- CDH11 | c.844G>A p.V282I | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs367827121; called by muse, mutect2, varscan2
- CDKN2D | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 13/384 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100224738; called by muse, mutect2
- CEL | c.860G>A p.R287Q (on ENST00000673714; = p.R284Q on NM_001807.6) | Missense Mutation (SNP) | VAF 212/482 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs748906749; called by muse, mutect2, varscan2
- CELSR1 | c.2777G>A p.R926H | Missense Mutation (SNP) | VAF 88/180 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765867356, COSV99418865; called by muse, mutect2, varscan2
- CELSR2 | c.5431G>A p.D1811N | Missense Mutation (SNP) | VAF 68/166 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.056); catalogued as rs547223441, COSV54774327; called by muse, mutect2, varscan2
- CELSR3 | c.9473C>T p.P3158L | Missense Mutation (SNP) | VAF 99/272 reads (36%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs373014167; called by muse, mutect2, varscan2
- CENPJ | c.2920C>T p.R974C | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs764688685; called by muse, mutect2, varscan2
- CEP126 | c.2870G>A p.R957Q | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.79); PolyPhen benign (0.014); catalogued as rs77742850, COSV54827919; called by muse, mutect2, varscan2
- CEP170B | c.2759C>T p.T920M (on ENST00000453495; = p.T849M on NM_015005.3) | Missense Mutation (SNP) | VAF 55/268 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs750128744, COSV69023817; called by muse, mutect2, varscan2
- CEP63 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 146/437 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs147553684, COSV59676084; called by muse, mutect2, varscan2
- CFAP410 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1197313970; called by muse, mutect2, varscan2
- CFAP45 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 107/292 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs779458678, COSV100928464; called by muse, mutect2, varscan2
- CHD1L | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1455863597; called by muse, mutect2, varscan2
- CHD5 | c.2429G>A p.R810H | Missense Mutation (SNP) | VAF 67/151 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs147522329; called by muse, mutect2, varscan2
- CHD8 | c.2099G>A p.R700H (on ENST00000646647 / NM_001170629.2; = p.R421H on NM_020920.4) | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1085307545; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHDH | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 52/127 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs781280891; called by muse, varscan2
- CHDH | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as rs911414140, COSV59459581; called by muse, varscan2
- CHRNB2 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 198/530 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs945159241; called by muse, mutect2, varscan2
- CHRNG | c.961G>A p.V321M | Missense Mutation (SNP) | VAF 102/464 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.1); catalogued as rs138637669; called by muse, mutect2, varscan2
- CILP | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 133/359 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1243095228; called by muse, mutect2, varscan2
- CLCF1 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 59/112 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs104894203, CM066008, COSV100425603; called by muse, mutect2, varscan2
- CLCN7 | c.410C>T p.T137M | Missense Mutation (SNP) | VAF 153/485 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1474822482; called by muse, mutect2, varscan2
- CLCNKA | c.1501G>A p.V501M | Missense Mutation (SNP) | VAF 157/362 reads (43%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.996); catalogued as rs772885800; called by muse, mutect2, varscan2
- CLDN14 | c.500G>A p.G167D | Missense Mutation (SNP) | VAF 24/218 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100578413; called by muse, mutect2, varscan2
- CLDN22 | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 90/223 reads (40%) | catalogued as rs376068009; called by muse, mutect2, varscan2
- CLEC4A | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 87/185 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs373496736, COSV99983588; called by muse, mutect2, varscan2
- CLIP1 | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 79/166 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs774785991, COSV56802870; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLIP2 | c.2953C>T p.R985W | Missense Mutation (SNP) | VAF 48/221 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs781813867; called by muse, mutect2, varscan2
- CLSTN1 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 129/299 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758488803, COSV63651496; called by muse, mutect2, varscan2
- CNOT1 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 125/319 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs745954288, COSV57776502; called by muse, mutect2, varscan2
- CNTNAP2 | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 152/528 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1241987279, COSV100672872, COSV62264200; called by muse, mutect2, varscan2
- COG2 | c.1756G>A p.A586T | Missense Mutation (SNP) | VAF 89/190 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs955603291, COSV64187029; called by muse, mutect2, varscan2
- COL20A1 | c.2252C>T p.S751L | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.774); catalogued as rs770819951, COSV58925894; called by muse, varscan2
- COL22A1 | c.70G>A p.G24S | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs761525542, COSV57329385, COSV57364269; called by muse, mutect2, varscan2
- COL4A3 | c.3722G>A p.R1241H | Missense Mutation (SNP) | VAF 44/434 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs201841428; called by muse, mutect2, varscan2
- COL4A4 | c.2752G>A p.G918R | Missense Mutation (SNP) | VAF 104/470 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372606845, CM148122, COSV61630020; called by muse, mutect2, varscan2
- COL4A6 | c.5012C>T p.T1671M | Missense Mutation (SNP) | VAF 101/259 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs763913956, COSV57861995; called by muse, mutect2, varscan2
- COL5A2 | c.3767C>T p.A1256V | Missense Mutation (SNP) | VAF 198/484 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as rs558404005; called by muse, mutect2, varscan2
- COL5A3 | c.3286G>A p.A1096T | Missense Mutation (SNP) | VAF 25/232 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.373); catalogued as rs763284986, COSV53406949; called by muse, mutect2, varscan2
- COL6A3 | c.2293G>A p.A765T | Missense Mutation (SNP) | VAF 129/357 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.195); catalogued as rs1256603031; called by muse, mutect2, varscan2
- COL6A3 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 69/198 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs769697782; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPAMD8 | c.2386G>A p.E796K (on ENST00000651564; = p.E749K on NM_015692.5) | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs531351431, COSV52230787; called by muse, mutect2, varscan2
- CPNE5 | c.1552G>A p.D518N | Missense Mutation (SNP) | VAF 82/199 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs759542006, COSV55201345; called by muse, mutect2, varscan2
- CPNE9 | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 63/131 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as rs373089220; called by muse, mutect2, varscan2
- CPSF1 | c.3679G>A p.V1227I | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.096); catalogued as rs782639339; called by muse, mutect2, varscan2
- CPT1A | c.1933C>T p.R645C | Missense Mutation (SNP) | VAF 147/317 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs367840385, COSV99681152; called by muse, mutect2, varscan2
- CPT1C | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs943269432; called by muse, mutect2, varscan2
- CRACDL | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs771734554; called by muse, mutect2, varscan2
- CREB3L4 | c.577_579del p.E193del | In Frame Del (DEL) | VAF 48/114 reads (42%) | catalogued as rs769844271; called by pindel, varscan2
- CREBBP | c.3914+2T>C p.X1305_splice | Splice Site (SNP) | VAF 138/395 reads (35%) | catalogued as COSV99270489; called by muse, mutect2, varscan2
- CROCC | c.2074G>A p.A692T | Missense Mutation (SNP) | VAF 72/414 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs778887976; called by muse, mutect2
- CROT | c.1253C>T p.T418M | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs147718012, COSV58972977; called by muse, mutect2, varscan2
- CS | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 80/149 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as rs779289848, COSV60832083, COSV60832337; called by muse, mutect2, varscan2
- CSF1 | c.1420G>A p.V474I | Missense Mutation (SNP) | VAF 75/175 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs548942397, COSV100294426; called by muse, mutect2, varscan2
- CSGALNACT1 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 171/418 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); catalogued as rs1194788527, COSV59976710, COSV59978644; called by muse, mutect2, varscan2
- CSHL1 | c.641G>A p.R214H (on ENST00000309894 / NM_022581.3; = p.R120H on NM_001318.4) | Missense Mutation (SNP) | VAF 107/452 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.102); catalogued as rs543435492; called by muse, mutect2, varscan2
- CSMD1 | c.1403C>T p.T468M (on ENST00000520002; = p.T467M on NM_033225.6) | Missense Mutation (SNP) | VAF 87/222 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1245639527, COSV104434177; called by muse, mutect2, varscan2
- CTAGE9 | c.2135G>A p.G712D | Missense Mutation (SNP) | VAF 43/745 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as rs1298968155; called by muse, mutect2
- CTCFL | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs767243354, COSV54776735; called by muse, mutect2, varscan2
- CTSK | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 24/345 reads (7%) | catalogued as rs759107967, COSV55011939; called by muse, mutect2
- CUL1 | c.1717C>T p.R573C | Missense Mutation (SNP) | VAF 108/399 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1211952562; called by muse, mutect2, varscan2
- CXCR2 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 63/162 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768791823, COSV59280832; called by muse, mutect2, varscan2
- CYP11B1 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 245/562 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs761472886, COSV99455153; called by muse, mutect2, varscan2
- CYP27B1 | c.974C>T p.T325M | Missense Mutation (SNP) | VAF 128/463 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56983977, COSV99141652; called by muse, mutect2, varscan2
- CYP46A1 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 81/193 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as rs1303404186; called by muse, mutect2, varscan2
- DBF4 | c.74dup p.N25Kfs*11 | Frame Shift Ins (INS) | VAF 24/84 reads (29%) | catalogued as rs762918884; called by mutect2, varscan2
- DCPS | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 58/624 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as rs781480975; called by muse, mutect2
- DCST1 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 142/365 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.137); catalogued as rs544612246, COSV55053225; called by muse, mutect2, varscan2
- DDR1 | c.2656C>T p.R886W (on ENST00000324771; = p.R849W on NM_001954.4) | Missense Mutation (SNP) | VAF 75/181 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs763588465; called by muse, mutect2, varscan2
- DDX11 | c.1276G>A p.V426M | Missense Mutation (SNP) | VAF 61/369 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377388469; called by muse, mutect2, varscan2
- DDX19B | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 11/118 reads (9%) | catalogued as COSV55364728; called by muse, mutect2
- DDX23 | c.2261G>A p.R754H | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56399237; called by muse, mutect2, varscan2
- DDX27 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.245); catalogued as rs374821878; called by muse, varscan2
- DDX27 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 53/189 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65629434; called by muse, varscan2
- DDX3X | c.1882G>A p.G628S (on ENST00000399959; = p.G629S on NM_001356.5) | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs1476609971; called by muse, mutect2, varscan2
- DDX46 | c.2126G>A p.R709Q | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62799680; called by muse, mutect2, varscan2
- DDX46 | c.3044G>A p.R1015Q | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0.087); catalogued as rs1217027167; called by muse, mutect2, varscan2
- DEPDC5 | c.2183G>A p.R728H (on ENST00000400246; = p.R797H on NM_014662.5) | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56692966; called by muse, mutect2
- DGAT1 | c.750C>T p.R250= | Splice Region (SNP) | VAF 11/17 reads (65%) | catalogued as rs782707652; called by muse, mutect2, varscan2
- DGAT2 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 90/206 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs1358254217; called by muse, mutect2, varscan2
- DHCR7 | c.52G>A p.V18I | Missense Mutation (SNP) | VAF 140/336 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs770947907; called by muse, mutect2, varscan2
- DHX29 | c.3034C>T p.R1012C | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748716619, COSV52417871; called by muse, mutect2, varscan2
- DHX34 | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 69/337 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs903106077, COSV60898398; called by muse, mutect2, varscan2
- DIAPH1 | c.1261C>T p.R421* | Nonsense Mutation (SNP) | VAF 130/277 reads (47%) | catalogued as rs1319624525; called by muse, mutect2, varscan2
- DIDO1 | c.3427C>T p.R1143C | Missense Mutation (SNP) | VAF 159/539 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.872); catalogued as rs1015453974, COSV99825188; called by muse, mutect2, varscan2
- DIXDC1 | c.1534G>A p.D512N (on ENST00000440460 / NM_001037954.4; = p.D301N on NM_033425.4) | Missense Mutation (SNP) | VAF 67/220 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs372805703; called by muse, varscan2
- DLL1 | c.1760C>T p.T587M | Missense Mutation (SNP) | VAF 24/364 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.34); catalogued as rs199850507; called by muse, mutect2
- DMAC2 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.046); catalogued as rs782664653, COSV55729053; called by muse, mutect2
- DMPK | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 29/380 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs753483995; called by muse, mutect2
- DMWD | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 65/289 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747892804; called by muse, mutect2, varscan2
- DNAAF5 | c.1997C>T p.A666V | Missense Mutation (SNP) | VAF 66/291 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs761189541, COSV52416835; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH10 | c.1685G>A p.R562H (on ENST00000409039; = p.R501H on NM_207437.3) | Missense Mutation (SNP) | VAF 17/179 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.071); catalogued as rs201031616, COSV68991821; called by muse, mutect2
- DNAH11 | c.11098G>A p.E3700K | Missense Mutation (SNP) | VAF 78/443 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs768652615, COSV60967492; called by muse, mutect2, varscan2
- DNAH17 | c.2941G>A p.E981K | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT tolerated (0.93); PolyPhen benign (0.018); catalogued as rs377586375; called by muse, mutect2, varscan2
- DNAH9 | c.13004C>T p.T4335M | Missense Mutation (SNP) | VAF 67/147 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as rs376563355; called by muse, mutect2, varscan2
- DNAJC13 | c.5707G>A p.V1903I | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs150102948; called by muse, mutect2, varscan2
- DNAJC21 | c.1660G>A p.A554T | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs745566489; called by muse, mutect2, varscan2
- DNALI1 | c.539G>A p.R180H (on ENST00000296218; = p.R158H on NM_003462.5) | Missense Mutation (SNP) | VAF 17/213 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.362); catalogued as rs771741737; called by muse, mutect2
- DNM2 | c.1837G>A p.V613M (on ENST00000355667 / NM_001005360.3; = p.V609M on NM_004945.3) | Missense Mutation (SNP) | VAF 46/507 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.462); catalogued as rs748286191; ClinVar: benign / likely benign; called by muse, mutect2
- DNM2 | c.2411_2413del p.F804del (on ENST00000355667 / NM_001005360.3; = p.F800del on NM_004945.3) | In Frame Del (DEL) | VAF 43/385 reads (11%) | catalogued as rs752014734; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- DNM2 | c.2561C>T p.A854V (on ENST00000355667 / NM_001005360.3; = p.A850V on NM_004945.3) | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.029); catalogued as rs776073354; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNTTIP1 | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 9/206 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1312760829, COSV65460837; called by muse, mutect2
- DNTTIP1 | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 77/316 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs767661063, COSV54755204; called by muse, mutect2, varscan2
- DOCK6 | c.5543G>A p.R1848H | Missense Mutation (SNP) | VAF 139/475 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as rs201858507; called by muse, mutect2, varscan2
- DOCK8 | c.2607C>T p.G869= | Splice Region (SNP) | VAF 254/473 reads (54%) | catalogued as rs760967651, COSV66617642; called by muse, mutect2, varscan2
- DOK5 | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 78/216 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.876); catalogued as rs752227134, COSV52823682; called by muse, mutect2, varscan2
- DPAGT1 | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 253/466 reads (54%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as rs896612042; called by muse, mutect2, varscan2
- DPYSL4 | c.1466C>T p.A489V | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs758420742, COSV53843189; called by muse, mutect2
- DRD5 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 78/187 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs774074172; called by muse, mutect2, varscan2
- DSCAM | c.2875C>T p.R959C | Missense Mutation (SNP) | VAF 166/375 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1419838292, COSV68031864; called by muse, mutect2, varscan2
- DSCAM | c.1765G>A p.V589I | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.32); catalogued as rs200358160, COSV68028771; called by muse, mutect2, varscan2
- DTX4 | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.849); catalogued as rs372858846; called by muse, mutect2
- DUSP26 | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 67/130 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs376826832, COSV56361434, COSV99823617; called by muse, mutect2, varscan2
- DUSP8 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1466784941; called by muse, mutect2, varscan2
- DUXA | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as rs746061596, COSV73729661; called by muse, mutect2, varscan2
- DVL3 | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs201442250, COSV57454752; called by muse, mutect2, varscan2
- E2F7 | c.2632G>A p.G878S | Missense Mutation (SNP) | VAF 56/203 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1460982930; called by muse, mutect2, varscan2
- ECSIT | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 173/645 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs889719091; called by muse, mutect2, varscan2
- EDEM3 | c.2162G>A p.R721H | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749617259, COSV58926674; called by muse, mutect2, varscan2
- EEFSEC | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 113/275 reads (41%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs761447043, COSV54631595; called by muse, mutect2, varscan2
- EIF3K | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 54/275 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.316); catalogued as rs1325669996; called by muse, mutect2, varscan2
- EIF4G3 | c.2428G>A p.A810T | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1215059821, COSV99945413; called by muse, mutect2
- ELFN1 | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.049); catalogued as rs764223756; called by muse, mutect2, varscan2
- ELFN2 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs371574699, COSV68744666; called by muse, mutect2, varscan2
- ELMO3 | c.1292C>T p.A431V (on ENST00000652269; = p.A378V on NM_024712.5) | Missense Mutation (SNP) | VAF 69/158 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.281); catalogued as rs776604078, COSV62607177; called by muse, mutect2, varscan2
- ELN | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 152/479 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.476); catalogued as rs199709542; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ELN | c.2008G>A p.A670T (on ENST00000320399 / NM_001278939.1; = p.A637T on NM_000501.4) | Missense Mutation (SNP) | VAF 162/622 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.206); catalogued as rs536177240; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ENPP1 | c.2416C>T p.R806C | Missense Mutation (SNP) | VAF 114/288 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as rs770659674; called by muse, mutect2, varscan2
- EOMES | c.1720G>T p.G574W | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99842074; called by muse, mutect2
- EP400 | c.1388C>T p.T463M | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as rs779183271, COSV57767928; called by muse, mutect2, varscan2
- EP400 | c.2785G>A p.V929I | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs924404499, COSV57790698; called by muse, mutect2, varscan2
- EPG5 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 76/193 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs745445439; called by muse, mutect2, varscan2
- EPHA1 | c.1178C>T p.S393L | Missense Mutation (SNP) | VAF 73/259 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as rs765890431; called by muse, mutect2, varscan2
- EPHA10 | c.2320C>T p.R774C | Missense Mutation (SNP) | VAF 84/307 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1427164882, COSV104397426; called by muse, mutect2, varscan2
- EPHA2 | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 173/405 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.658); catalogued as rs369605778; called by muse, mutect2, varscan2
- EPHB2 | c.65C>T p.T22M | Missense Mutation (SNP) | VAF 121/334 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs201121087, COSV65865894; called by muse, mutect2, varscan2
- EPHB6 | c.2057G>A p.R686H | Missense Mutation (SNP) | VAF 42/568 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs753358072; called by muse, mutect2
- ERAS | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as COSV54432492; called by muse, mutect2, varscan2
- ERMARD | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765837818, COSV64648936; called by muse, mutect2, varscan2
- ESM1 | c.9C>G p.S3R | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs539161576; called by muse, mutect2
- ESR2 | c.1541C>T p.P514L | Missense Mutation (SNP) | VAF 84/162 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs565210086, COSV99962873; called by muse, mutect2, varscan2
- EVC | c.1174_1176del p.E392del | In Frame Del (DEL) | VAF 185/570 reads (32%) | catalogued as rs1560340281; called by pindel, varscan2
- EVPL | c.3841G>A p.V1281I | Missense Mutation (SNP) | VAF 76/198 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.726); catalogued as rs779717113; called by muse, mutect2, varscan2
- EXOC1 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.233); catalogued as COSV62119831; called by muse, mutect2, varscan2
- EXOC5 | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1263279962; called by muse, mutect2, varscan2
- FAM163B | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 76/175 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs767403214; called by muse, mutect2, varscan2
- FAM214A | c.2042del p.N681Mfs*5 | Frame Shift Del (DEL) | VAF 26/61 reads (43%) | catalogued as rs762546731, COSV55927849; called by mutect2, varscan2
- FAM219A | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.018); catalogued as rs752461701; called by muse, mutect2, varscan2
- FAM220A | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 98/256 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs767978398; called by muse, mutect2, varscan2
- FAM47B | c.1594C>T p.R532C | Missense Mutation (SNP) | VAF 83/160 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs773159030, COSV61452348; called by muse, mutect2, varscan2
- FAM50A | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99340789; called by muse, mutect2, varscan2
- FAM53A | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 60/242 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1302039192; called by muse, mutect2, varscan2
- FANCA | c.2008C>T p.R670C | Missense Mutation (SNP) | VAF 113/320 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.183); catalogued as rs587778312, COSV66885128; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- FANCC | c.1265T>C p.L422P | Missense Mutation (SNP) | VAF 126/291 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV56659893; called by muse, mutect2, varscan2
- FANCC | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 136/337 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs778951584, COSV100002114, COSV56668025; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAT2 | c.7808C>T p.P2603L | Missense Mutation (SNP) | VAF 88/151 reads (58%) | SIFT tolerated (0.26); PolyPhen probably damaging (1); catalogued as rs372313673; called by muse, mutect2, varscan2
- FAT2 | c.3839C>T p.T1280I | Missense Mutation (SNP) | VAF 71/285 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs778654059; called by muse, mutect2, varscan2
- FBLIM1 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 95/119 reads (80%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs773720927; called by muse, mutect2, varscan2
- FBLN2 | c.2143G>A p.V715M | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.773); catalogued as rs200141144; called by muse, mutect2, varscan2
- FBLN7 | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as rs1558895507; called by muse, mutect2, varscan2
- FCAR | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 109/381 reads (29%) | SIFT tolerated (0.91); PolyPhen benign (0.014); catalogued as rs750370550, COSV62028733; called by muse, mutect2, varscan2
- FCGBP | c.4625C>T p.A1542V | Missense Mutation (SNP) | VAF 95/725 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs782371566; called by muse, varscan2
- FCSK | c.1369G>A p.V457M | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs375968247; called by muse, mutect2, varscan2
- FDXR | c.883C>T p.R295C (on ENST00000293195 / NM_024417.5; = p.R301C on NM_004110.6) | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs373171895; called by muse, mutect2, varscan2
- FES | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs922763509, COSV51578745; called by muse, mutect2, varscan2
- FHDC1 | c.3377G>A p.R1126Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs895333454; called by muse, mutect2, varscan2
- FIBCD1 | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs574432580; called by muse, mutect2, varscan2
- FIG4 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 145/318 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0.062); catalogued as rs188547769, COSV57787648; called by muse, mutect2, varscan2
- FIGNL1 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 58/202 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63553302; called by muse, mutect2, varscan2
- FILIP1L | c.1637C>T p.A546V (on ENST00000354552 / NM_182909.3; = p.A306V on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.589); catalogued as rs373504477; called by muse, mutect2, varscan2
- FKBP8 | c.1094G>A p.R365Q (on ENST00000222308 / NM_001308373.2; = p.R366Q on NM_012181.5) | Missense Mutation (SNP) | VAF 72/236 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.059); catalogued as rs1335030032; called by muse, mutect2, varscan2
- FLII | c.3124C>T p.R1042W | Missense Mutation (SNP) | VAF 103/331 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs1250289073; called by muse, mutect2, varscan2
- FLII | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370401968; called by muse, mutect2, varscan2
- FLYWCH1 | c.484C>T p.R162* (on ENST00000253928 / NM_001308068.2; = p.R161* on NM_020912.1 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 70/229 reads (31%) | catalogued as rs752366311; called by muse, mutect2, varscan2
- FN1 | c.3517C>T p.P1173S | Missense Mutation (SNP) | VAF 89/237 reads (38%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as rs1224176023, COSV60551251; called by muse, mutect2, varscan2
- FN1 | c.1703C>T p.T568M | Missense Mutation (SNP) | VAF 135/328 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as rs770837561, COSV100117627; called by muse, mutect2, varscan2
- FPR3 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1435600197; called by muse, mutect2, varscan2
- FRAS1 | c.309+3_309+6del p.X103_splice | Splice Site (DEL) | VAF 45/156 reads (29%) | catalogued as rs1221996131; called by mutect2, pindel, varscan2
- FSTL4 | c.1135G>A p.V379M | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs376207233; called by muse, mutect2
- FTMT | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 32/207 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs531790984; called by muse, mutect2, varscan2
- FZD9 | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 88/318 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.108); catalogued as rs139948155; called by muse, mutect2, varscan2
- GABRE | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs753240533, COSV100944359; called by muse, mutect2, varscan2
- GALNTL6 | c.1235C>T p.T412M | Missense Mutation (SNP) | VAF 95/252 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as rs755485297, COSV101560119, COSV101560222; called by muse, varscan2
- GALR3 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV50764613; called by muse, mutect2, varscan2
- GAREM2 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 195/515 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.695); catalogued as rs1425303330; called by muse, mutect2, varscan2
- GARRE1 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 81/232 reads (35%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as rs756723580; called by muse, mutect2, varscan2
- GAS8 | c.1141_1143del p.K381del | In Frame Del (DEL) | VAF 146/378 reads (39%) | catalogued as rs760468250; called by pindel, varscan2
- GBP7 | c.897C>A p.Y299* | Nonsense Mutation (SNP) | VAF 34/90 reads (38%) | catalogued as rs768193411, COSV54009303; called by muse, mutect2, varscan2
- GDF6 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 88/207 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV54623423; called by muse, mutect2, varscan2
- GEMIN4 | c.2867C>T p.A956V | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs369029997; called by muse, mutect2, varscan2
- GFRA1 | c.544G>A p.V182M | Missense Mutation (SNP) | VAF 79/117 reads (68%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as rs752981166, COSV62611549; called by muse, mutect2, varscan2
- GGH | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376001011; called by muse, mutect2, varscan2
- GHITM | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 58/88 reads (66%) | SIFT tolerated (0.1); PolyPhen benign (0.367); catalogued as rs1014357608; called by muse, mutect2, varscan2
- GIGYF1 | c.1249G>A p.G417R | Missense Mutation (SNP) | VAF 112/387 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.486); catalogued as rs759049480; called by muse, mutect2, varscan2
- GIMAP8 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs750332789, COSV56232423; called by muse, varscan2
- GIPC1 | c.149dup p.P51Sfs*132 | Frame Shift Ins (INS) | VAF 46/184 reads (25%) | catalogued as rs771881138; called by mutect2, varscan2
- GLIS2 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 94/246 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs377037409; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLP2R | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 91/230 reads (40%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs146116783; called by muse, mutect2, varscan2
- GLYCTK | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 121/288 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0.031); catalogued as rs751195851; called by muse, mutect2, varscan2
- GNAT3 | c.313C>T p.R105* | Nonsense Mutation (SNP) | VAF 39/132 reads (30%) | catalogued as rs200422530; called by muse, mutect2
- GOLGA3 | c.2791G>A p.E931K | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.331); catalogued as rs772025497, COSV52644357; called by muse, varscan2
- GOLGA6L2 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.553); catalogued as rs566940056, COSV61475075; called by muse, mutect2, varscan2
- GPLD1 | c.2019C>T p.Y673= | Splice Region (SNP) | VAF 61/140 reads (44%) | catalogued as rs140430161; called by muse, mutect2, varscan2
- GPR1 | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 63/147 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as rs781277858, COSV67977692; called by muse, mutect2, varscan2
- GPR101 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99981284; called by muse, mutect2, varscan2
- GPR17 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs376520675; called by muse, mutect2, varscan2
- GPR6 | c.112C>G p.P38A | Missense Mutation (SNP) | VAF 69/194 reads (36%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV51571233; called by muse, mutect2, varscan2
- GPR78 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as rs769666701, COSV101224053; called by muse, mutect2, varscan2
- GPR87 | c.652G>A p.V218M | Missense Mutation (SNP) | VAF 122/260 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs777076331, COSV53463602; called by muse, mutect2, varscan2
- GPS2 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as rs192050225, COSV59746973; called by muse, mutect2, varscan2
- GRHL1 | c.1847C>T p.T616M | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.313); catalogued as rs143356570; called by muse, mutect2, varscan2
- GRID2IP | c.2029C>T p.R677C | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as rs914939297; called by muse, mutect2, varscan2
- GRID2IP | c.1615G>A p.D539N | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1041314777, COSV70692239; called by muse, mutect2
- GRID2IP | c.1555G>A p.G519S | Missense Mutation (SNP) | VAF 86/224 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs886359056, COSV70692000; called by muse, varscan2
- GRID2IP | c.1492C>T p.R498W | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs371155207; called by muse, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 16/114 reads (14%) | catalogued as rs760757380; called by mutect2, varscan2
- GRM2 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 93/260 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs777314733, COSV56583290, COSV56583698; called by muse, mutect2, varscan2
- GSDMB | c.491C>T p.T164M | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as rs1463326353, COSV58782630; called by muse, mutect2
- HAO1 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 84/274 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.201); catalogued as rs200686504, COSV66493396; called by muse, mutect2, varscan2
- HAS1 | c.1171G>A p.A391T | Missense Mutation (SNP) | VAF 143/465 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.588); catalogued as rs1279852039; called by muse, mutect2, varscan2
- HCFC1 | c.4549C>T p.R1517W | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.333); catalogued as rs1557113069, COSV60069992; called by muse, mutect2, varscan2
- HCFC1 | c.3731G>A p.R1244H | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs782013532; called by muse, mutect2, varscan2
- HEATR6 | c.1963C>T p.R655* | Nonsense Mutation (SNP) | VAF 57/157 reads (36%) | catalogued as rs375151458; called by muse, mutect2, varscan2
- HELZ2 | c.6998G>A p.R2333Q (on ENST00000467148 / NM_001037335.2; = p.R1764Q on NM_033405.3) | Missense Mutation (SNP) | VAF 59/195 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as rs371582514; called by muse, mutect2, varscan2
- HERC2 | c.9937C>T p.R3313C | Missense Mutation (SNP) | VAF 100/241 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs552730343; called by muse, mutect2, varscan2
- HEXD | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 70/137 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as rs749879786, COSV60066080; called by muse, mutect2, varscan2
- HIPK2 | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 112/388 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.362); catalogued as rs536171726; called by muse, mutect2, varscan2
- HK2 | c.1748C>T p.A583V | Missense Mutation (SNP) | VAF 277/656 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.427); catalogued as rs201342639; called by muse, mutect2, varscan2
- HMCN2 | c.14071G>A p.G4691R | Missense Mutation (SNP) | VAF 77/208 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1465988116; called by muse, mutect2, varscan2
- HNRNPUL1 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as rs760933060, COSV54565381, COSV54565700; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 49/223 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs866321641; called by muse, mutect2, varscan2
- HPS3 | c.2699G>A p.R900H | Missense Mutation (SNP) | VAF 129/356 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as rs202157837, COSV56052672; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HRH1 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 76/230 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as rs759549068, COSV99081383; called by muse, varscan2
- HRH3 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 107/359 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs754804647; called by muse, mutect2, varscan2
- HS3ST1 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs568292548, COSV99137084; called by muse, mutect2, varscan2
- HSPA12A | c.1757G>A p.R586H | Missense Mutation (SNP) | VAF 111/147 reads (76%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs375255169; called by muse, mutect2, varscan2
- HSPA4 | c.1841G>A p.R614Q | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as rs865943834; called by muse, mutect2, varscan2
- HTR1E | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs1269240588; called by muse, mutect2, varscan2
- HTR3A | c.1306C>T p.R436* | Nonsense Mutation (SNP) | VAF 121/384 reads (32%) | catalogued as rs373514819; called by muse, mutect2, varscan2
- HUNK | c.1039G>A p.V347I | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.509); catalogued as rs1200488084; called by muse, mutect2, varscan2
- HYDIN | c.14582C>T p.S4861L | Missense Mutation (SNP) | VAF 24/476 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs775704796, COSV66641460; called by muse, mutect2
- HYDIN | c.1948C>T p.R650C | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs140028548; called by muse, mutect2, varscan2
- IDH3B | c.1051_1053del p.K351del | In Frame Del (DEL) | VAF 212/728 reads (29%) | catalogued as rs774653761; called by pindel, varscan2
- IFIH1 | c.2527C>T p.H843Y | Missense Mutation (SNP) | VAF 68/211 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs772170648, COSV55127101, COSV55130411; called by muse, mutect2, varscan2
- IFT140 | c.4181C>T p.T1394M | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs771765849; called by muse, mutect2, varscan2
- IFT140 | c.3052C>T p.R1018C | Missense Mutation (SNP) | VAF 62/106 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs767290624; called by muse, mutect2, varscan2
- IGF1R | c.3869C>T p.P1290L | Missense Mutation (SNP) | VAF 62/186 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs760362276, COSV51278562; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGHG3 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 202/483 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.165); catalogued as rs745813727; called by muse, mutect2, varscan2
- IGLL1 | c.491C>T p.T164M | Missense Mutation (SNP) | VAF 285/673 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.793); catalogued as rs141766631; called by muse, mutect2, varscan2
- IGSF21 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 58/151 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as rs750165722, COSV52138814; called by muse, mutect2, varscan2
- IKZF4 | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1029640606, COSV100009384; called by muse, mutect2, varscan2
- IL10RA | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 105/552 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs144476761; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IL16 | c.1717C>T p.R573W | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs761395297; called by muse, mutect2, varscan2
- IL17RB | c.1198G>A p.V400I | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs199637339; called by muse, mutect2, varscan2
- IL17RD | c.1978C>T p.R660W | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs756741660, COSV56339002; called by muse, mutect2, varscan2
- IL27RA | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs201794701, COSV54601246; called by muse, mutect2, varscan2
- ILDR1 | c.1496C>T p.S499L (on ENST00000344209 / NM_001199799.2; = p.S455L on NM_175924.4) | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.213); catalogued as rs761333724; called by muse, mutect2, varscan2
- INPP5D | c.3029C>T p.P1010L (on ENST00000445964 / NM_001017915.3; = p.P1009L on NM_005541.5) | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs61752228; called by muse, mutect2, varscan2
- INPPL1 | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs896238433; called by muse, mutect2, varscan2
- INS-IGF2 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 67/173 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as rs1184417816, COSV51748141; called by muse, mutect2, varscan2
- INTS2 | c.940C>T p.R314W | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1433760940, COSV52152071, COSV99248010; called by muse, mutect2, varscan2
- IQCE | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 57/177 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs188929365, COSV100383589; called by muse, mutect2, varscan2
- IQCN | c.346G>A p.G116S | Missense Mutation (SNP) | VAF 39/389 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs1336626651; called by muse, mutect2
- IQGAP3 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 61/132 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs370931618; called by muse, mutect2, varscan2
- IQSEC1 | c.2622G>A p.S874= | Splice Region (SNP) | VAF 51/117 reads (44%) | catalogued as rs776819752, COSV56221110; called by muse, mutect2, varscan2
- IQSEC3 | c.1376C>T p.A459V (on ENST00000538872 / NM_001170738.2; = p.A156V on NM_015232.1) | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs572367293, COSV58288542; called by muse, mutect2, varscan2
- IRF2BP1 | c.1324G>A p.G442R | Missense Mutation (SNP) | VAF 11/206 reads (5%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.738); catalogued as rs1265037774, COSV56193217; called by muse, mutect2
- IRGC | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT tolerated (0.9); PolyPhen benign (0.395); catalogued as rs368220155; called by muse, mutect2, varscan2
- ISLR | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.594); catalogued as rs919871053; called by muse, mutect2, varscan2
- ISM1 | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 59/240 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs753984610, COSV99339807; called by muse, mutect2, varscan2
- ISYNA1 | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 99/325 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1453341017; called by muse, mutect2, varscan2
- ITGA7 | c.3038G>A p.R1013H (on ENST00000555728; = p.R969H on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 146/297 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs762923857, COSV57700601; called by muse, mutect2, varscan2
- ITGAX | c.1393G>A p.V465M | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs767824543, COSV99191500; called by muse, mutect2, varscan2
- ITGB2 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 135/408 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs749222328, CM151555, COSV56611334; called by muse, mutect2, varscan2
- ITGB2 | c.116C>T p.S39L | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs368899902, COSV56611985; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITGBL1 | c.185T>C p.L62P | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs770838447; called by muse, varscan2
- ITIH1 | c.304G>A p.V102I | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs373768121; called by muse, mutect2, varscan2
- ITIH3 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 72/243 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs373638980; called by muse, mutect2, varscan2
- ITIH6 | c.3755G>A p.R1252Q | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV54492618, COSV54495825; called by muse, mutect2, varscan2
- JADE2 | c.16C>T p.R6* | Nonsense Mutation (SNP) | VAF 52/127 reads (41%) | catalogued as rs1435018199, COSV50913185; called by muse, mutect2, varscan2
- JMJD6 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.513); catalogued as rs769402176, COSV58300838; called by muse, mutect2, varscan2
- JPT1 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 74/148 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs868058942, COSV59173129; called by muse, mutect2, varscan2
- JUP | c.1714C>T p.R572W | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs559297418, COSV60280205; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KALRN | c.6055G>A p.V2019M (on ENST00000360013 / NM_001024660.4; = p.V322M on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/214 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139149462; called by muse, mutect2, varscan2
- KATNIP | c.4363G>A p.V1455I | Missense Mutation (SNP) | VAF 68/177 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.053); catalogued as rs201599601; called by muse, mutect2, varscan2
- KBTBD12 | c.113_115del p.E38del | In Frame Del (DEL) | VAF 72/206 reads (35%) | catalogued as rs577666989; called by mutect2, pindel, varscan2
- KCNC3 | c.1249C>T p.R417C | Missense Mutation (SNP) | VAF 150/578 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV65387264; called by muse, mutect2, varscan2
- KCNH3 | c.2123del p.G708Efs*11 | Frame Shift Del (DEL) | VAF 34/103 reads (33%) | catalogued as rs1229306184; called by mutect2, varscan2
- KCNH4 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 93/277 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as rs888413832, COSV52919734; called by muse, mutect2, varscan2
- KCNH6 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 70/189 reads (37%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.545); catalogued as rs941008639, COSV59008728; called by muse, mutect2, varscan2
- KCNJ16 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 106/269 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs769285903, COSV99388825; called by muse, mutect2, varscan2
- KCNJ5 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 132/488 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs1565551461, COSV100610761, COSV57966536; called by muse, mutect2, varscan2
- KCNK17 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as rs368816680; called by muse, mutect2, varscan2
- KCNU1 | c.2570G>A p.R857Q | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs763915966, COSV67753864, COSV67753916; called by muse, mutect2, varscan2
- KDM5C | c.4379G>A p.R1460Q | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs1556832572; called by muse, mutect2
- KIAA1671 | c.2771C>T p.P924L | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as rs367786792; called by muse, mutect2, varscan2
- KIF13A | c.3086G>A p.R1029H | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1039150543, COSV99035611; called by muse, mutect2, varscan2
- KIF1A | c.4871G>A p.R1624Q (on ENST00000320389 / NM_001379639.1; = p.R1616Q on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/165 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760970824; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF21B | c.4255G>A p.A1419T (on ENST00000422435 / NM_001252100.2; = p.A1406T on NM_017596.4) | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.32); catalogued as rs771767165; called by muse, mutect2, varscan2
- KIF26A | c.1474G>A p.V492M | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.116); catalogued as rs751129821, COSV100181445, COSV59470186; called by muse, mutect2
- KIF26B | c.1636G>A p.G546S | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1334249011; called by muse, mutect2, varscan2
- KIF7 | c.3062G>A p.R1021H | Missense Mutation (SNP) | VAF 66/145 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs1416932636, COSV51541199; called by muse, mutect2, varscan2
- KIF7 | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 16/345 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1403008224, COSV99081096; called by muse, mutect2
- KIRREL3 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as rs546310584, COSV73106273; called by muse, mutect2, varscan2
- KLHDC4 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1041443500, COSV99566357; called by muse, mutect2, varscan2
- KLHDC8A | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 146/408 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.474); catalogued as rs776955533; called by muse, mutect2
- KLHL36 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs774996011; called by muse, varscan2
- KLHL36 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 74/188 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs999362327, COSV50727100; called by muse, varscan2
- KMT2D | c.15004C>T p.R5002W | Missense Mutation (SNP) | VAF 181/360 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs768594066, COSV56486902; called by muse, mutect2, varscan2
- KMT2D | c.957G>A p.A319= | Splice Region (SNP) | VAF 55/90 reads (61%) | catalogued as rs569941378; called by muse, mutect2, varscan2
- KMT5C | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 40/264 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.265); catalogued as rs1242515388; called by muse, mutect2, varscan2
- KPTN | c.907G>A p.G303S | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as rs775989501; called by muse, mutect2, varscan2
- KRT12 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 100/201 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1308897791; called by muse, mutect2
- KRT38 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs1403730511, COSV55845758; called by muse, mutect2, varscan2
- KRTAP20-2 | c.113G>A p.G38D | Missense Mutation (SNP) | VAF 126/426 reads (30%) | PolyPhen probably damaging (0.988); catalogued as COSV58183043; called by muse, mutect2, varscan2
- KYNU | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 79/212 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51584504; called by muse, mutect2, varscan2
- L3MBTL2 | c.1826C>T p.P609L | Missense Mutation (SNP) | VAF 64/97 reads (66%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs758863629, COSV99346157; called by muse, mutect2, varscan2
- LAMA5 | c.4447+1G>A p.X1483_splice | Splice Site (SNP) | VAF 16/138 reads (12%) | catalogued as rs767977705; called by muse, mutect2, varscan2
- LAMB4 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 85/300 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.261); catalogued as rs371458946; called by muse, mutect2, varscan2
- LDHB | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.461); catalogued as CM930470, COSV63365566; called by muse, mutect2
- LDHD | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 23/273 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs771516114, COSV100097115; called by muse, mutect2
- LGI3 | c.808C>T p.R270* | Nonsense Mutation (SNP) | VAF 50/143 reads (35%) | catalogued as rs778679674, COSV60443171, COSV60444265; called by muse, mutect2, varscan2
- LMBR1L | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs772511664, COSV57267143; called by muse, mutect2, varscan2
- LMNB2 | c.1412C>T p.S471L | Missense Mutation (SNP) | VAF 246/900 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs761548544, COSV57589680; called by muse, mutect2, varscan2
- LMO3 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 90/116 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53781944, COSV53784522; called by muse, mutect2, varscan2
- LONP1 | c.1943C>T p.P648L | Missense Mutation (SNP) | VAF 82/332 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs771259377; called by muse, mutect2
- LONP2 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 82/171 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); catalogued as rs763860627, COSV53520629, COSV99589549; called by muse, mutect2, varscan2
- LPP | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 87/195 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs183529256; called by muse, mutect2, varscan2
- LRP1B | c.5255C>T p.S1752L | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs761567956, COSV67215776; called by muse, varscan2
- LRP8 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 108/252 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs1364119120, COSV100036263; called by muse, mutect2, varscan2
- LRRC37A3 | c.1747C>T p.R583* | Nonsense Mutation (SNP) | VAF 40/166 reads (24%) | catalogued as rs1420117198; called by mutect2, varscan2
- LRRK2 | c.1073C>T p.T358M | Missense Mutation (SNP) | VAF 79/160 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs141262110; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- LRRTM4 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 80/198 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs200699710, COSV69139157, COSV69140155; called by muse, mutect2, varscan2
- LSM11 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs141199540; called by muse, mutect2
- LSM14A | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 98/381 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs1256995731; called by muse, mutect2, varscan2
- LYPD6 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.071); catalogued as rs201110764, COSV61938657; called by muse, mutect2, varscan2
- MACROH2A1 | c.154G>A p.V52I | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1561667702; called by muse, mutect2, varscan2
- MAD1L1 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs374019420; called by muse, mutect2, varscan2
- MAP1S | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 116/428 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); catalogued as rs755070623; called by muse, mutect2, varscan2
- MAP3K10 | c.1561G>A p.V521M | Missense Mutation (SNP) | VAF 101/282 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.34); catalogued as rs374566110; called by muse, varscan2
- MAP3K14 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 69/208 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.353); catalogued as rs1171942156; called by muse, mutect2, varscan2
- MAP3K5 | c.1771G>A p.V591M | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs760179645; called by muse, mutect2, varscan2
- MAP3K9 | c.2362C>T p.R788W (on ENST00000554752 / NM_001284230.1; = p.R802W on NM_033141.4) | Missense Mutation (SNP) | VAF 74/213 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as rs768511767; called by muse, mutect2, varscan2
- MAP7D1 | c.1233G>A p.P411= | Splice Region (SNP) | VAF 7/19 reads (37%) | catalogued as COSV60214865; called by muse, mutect2, varscan2
- MARK4 | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1296870778; called by muse, varscan2
- MASP2 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 31/273 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142614617; called by muse, mutect2, varscan2
- MAST1 | c.4324C>T p.R1442W | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.329); catalogued as COSV52245082; called by muse, mutect2
- MBD4 | c.673T>C p.F225L | Missense Mutation (SNP) | VAF 87/208 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV51445237; called by muse, mutect2, varscan2
- MBOAT7 | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.639); catalogued as rs753504958; called by muse, mutect2
- MC2R | c.676G>A p.G226R | Missense Mutation (SNP) | VAF 120/294 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761911005, CM160060; called by muse, mutect2, varscan2
- MCOLN1 | c.1012C>T p.R338W | Missense Mutation (SNP) | VAF 27/273 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs139729140; called by muse, varscan2
- MCOLN1 | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 96/282 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs781198432, COSV51181648; called by muse, varscan2
- MCOLN1 | c.1456C>T p.R486C | Missense Mutation (SNP) | VAF 180/626 reads (29%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV51174021; called by muse, varscan2
- MDC1 | c.3649C>T p.R1217* | Nonsense Mutation (SNP) | VAF 50/102 reads (49%) | catalogued as rs1562095881, COSV64524952; called by muse, varscan2
- MED14 | c.4061C>T p.T1354M | Missense Mutation (SNP) | VAF 116/310 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as COSV100247377; called by muse, mutect2, varscan2
- MFSD14B | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs765932214, COSV64701660; called by muse, mutect2, varscan2
- MGAM | c.4708C>T p.R1570C | Missense Mutation (SNP) | VAF 88/416 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267601326, COSV72074844; called by muse, mutect2, varscan2
- MIA2 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.172); catalogued as rs545707783, COSV54481923; called by muse, mutect2, varscan2
- MINDY4 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 34/551 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.312); catalogued as rs749042845, COSV54674587; called by muse, mutect2
- MMUT | c.1532G>A p.R511Q | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as rs776065390, COSV99222542; called by muse, mutect2, varscan2
- MORN1 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371150115; called by muse, mutect2, varscan2
- MORN3 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 99/207 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as rs781945068; called by muse, mutect2, varscan2
- MPG | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 148/305 reads (49%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs112187829; called by muse, mutect2, varscan2
- MPP3 | c.222+1G>A p.X74_splice | Splice Site (SNP) | VAF 33/163 reads (20%) | catalogued as rs757876775, COSV68197599; called by muse, mutect2, varscan2
- MRGPRX2 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 100/228 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs181882698; called by muse, mutect2, varscan2
- MRNIP | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 32/74 reads (43%) | catalogued as rs763677235, COSV52973897; called by muse, mutect2, varscan2
- MROH5 | c.3901G>A p.A1301T | Missense Mutation (SNP) | VAF 82/228 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs528744372; called by muse, mutect2, varscan2
- MRPL47 | c.443A>G p.E148G | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs887794619; called by muse, mutect2
- MRTFA | c.1649C>T p.T550M | Missense Mutation (SNP) | VAF 112/156 reads (72%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs757522554; called by muse, mutect2, varscan2
- MSANTD3 | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 90/255 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs746367895, COSV58492228; called by muse, mutect2, varscan2
- MSGN1 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 107/201 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.178); catalogued as rs753887996, COSV99808861; called by muse, mutect2, varscan2
- MSRB2 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 61/99 reads (62%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.906); catalogued as rs1411767051, COSV64738176; called by muse, mutect2, varscan2
- MTG2 | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs746237587; called by muse, mutect2, varscan2
- MUC16 | c.39725G>A p.R13242H | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated, low confidence (0.72); PolyPhen probably damaging (0.928); catalogued as rs543370542, COSV66692131; called by muse, mutect2
- MUC16 | c.13783C>T p.P4595S | Missense Mutation (SNP) | VAF 56/254 reads (22%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.067); catalogued as rs772002443; called by muse, mutect2, varscan2
- MUC17 | c.6943G>A p.E2315K | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.19); catalogued as COSV60282532; called by muse, varscan2
- MUC17 | c.12700G>A p.G4234R | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs780274013; called by muse, mutect2, varscan2
- MUC19 | c.1523G>A p.R508H | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.11); catalogued as rs190930617; called by muse, mutect2, varscan2
- MUC2 | c.2357C>T p.T786M | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as rs764883867; called by muse, mutect2, varscan2
- MXD4 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs772082970, COSV61466455; called by muse, mutect2, varscan2
- MYCBPAP | c.1534C>T p.R512* | Nonsense Mutation (SNP) | VAF 95/271 reads (35%) | catalogued as rs780386618; called by muse, mutect2, varscan2
- MYH4 | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 77/220 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1403812184; called by muse, mutect2, varscan2
- MYO16 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1212716166, COSV51824082; called by muse, mutect2, varscan2
- MYO1C | c.392G>A p.R131H (on ENST00000648651 / NM_001080779.2; = p.R96H on NM_033375.5) | Missense Mutation (SNP) | VAF 85/187 reads (45%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.75); catalogued as rs772254609, COSV62998363; called by muse, mutect2, varscan2
- MYO1E | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 131/333 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758478367; called by muse, mutect2, varscan2
- MYO3A | c.2719G>A p.D907N | Missense Mutation (SNP) | VAF 187/250 reads (75%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs727503325; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYOT | c.1363C>T p.R455W | Missense Mutation (SNP) | VAF 102/302 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs761598206; called by muse, mutect2, varscan2
- MYPOP | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs897106324; called by muse, varscan2
- MYRF | c.628G>A p.E210K (on ENST00000278836 / NM_001127392.3; = p.E201K on NM_013279.4) | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as rs565045590; called by muse, mutect2, varscan2
- MYRFL | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 62/181 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1173049422; called by muse, mutect2, varscan2
- MZF1 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 100/370 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs763241551; called by muse, mutect2, varscan2
- NAA80 | c.199C>T p.R67C (on ENST00000417393 / NM_001200018.2; = p.R89C on NM_012191.4) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs782774866; called by muse, mutect2, varscan2
- NAALAD2 | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 65/145 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775903355, COSV58962344; called by muse, mutect2, varscan2
- NAALADL1 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 65/164 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs776344083, COSV60524733; called by muse, mutect2, varscan2
- NAP1L1 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1249867501; called by muse, mutect2, varscan2
- NARS2 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757999669; called by muse, mutect2, varscan2
- NBAS | c.1522C>T p.R508C | Missense Mutation (SNP) | VAF 103/232 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs367964914; called by muse, mutect2, varscan2
- NCKIPSD | c.674C>T p.T225M | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs754519346, COSV99583820; called by muse, mutect2, varscan2
- NCKIPSD | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139134046; called by muse, mutect2
- NCOA2 | c.2534A>G p.Q845R | Missense Mutation (SNP) | VAF 56/598 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.99); catalogued as rs1227416239; called by muse, mutect2
- NEB | c.13768G>A p.A4590T | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as rs759568612; called by muse, mutect2, varscan2
- NEB | c.12931G>A p.A4311T | Missense Mutation (SNP) | VAF 78/182 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750215416, COSV51017285; called by muse, mutect2, varscan2
- NELFCD | c.292G>A p.A98T (on ENST00000602795; = p.A80T on NM_198976.4) | Missense Mutation (SNP) | VAF 69/280 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs751386529, COSV59745467; called by muse, mutect2, varscan2
- NEO1 | c.3340G>A p.V1114I | Missense Mutation (SNP) | VAF 47/253 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs778709112, COSV56070154; called by muse, mutect2, varscan2
- NEXMIF | c.1021G>A p.V341I | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs745417882; called by muse, mutect2, varscan2
- NFRKB | c.2663C>G p.P888R (on ENST00000446488 / NM_001143835.2; = p.P913R on NM_006165.3) | Missense Mutation (SNP) | VAF 36/243 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.802); catalogued as rs1386032554; called by muse, mutect2, varscan2
- NGF | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 182/478 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs778266438, COSV65687098; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NID2 | c.3103del p.R1035Gfs*67 | Frame Shift Del (DEL) | VAF 22/150 reads (15%) | catalogued as COSV53499514; called by mutect2, pindel, varscan2
- NIN | c.1414C>T p.R472C | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747426018, COSV55379784; called by muse, mutect2
- NLRP2 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 76/687 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.41); catalogued as rs758071463; called by muse, mutect2, varscan2
- NLRP2 | c.3041G>A p.R1014Q | Missense Mutation (SNP) | VAF 175/672 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs759064470, COSV99672306; called by muse, mutect2, varscan2
- NOC4L | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as rs148535195; called by muse, mutect2, varscan2
- NOM1 | c.1783G>A p.V595I | Missense Mutation (SNP) | VAF 76/235 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as rs149569042; called by muse, mutect2, varscan2
- NOS3 | c.2447G>A p.R816H | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.885); catalogued as rs1170693777; called by muse, mutect2, varscan2
- NOXA1 | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.082); catalogued as rs760381759; called by muse, varscan2
- NOXO1 | c.674C>T p.P225L (on ENST00000397280 / NM_172168.3; = p.P219L on NM_144603.4) | Missense Mutation (SNP) | VAF 12/179 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs1420786942; called by muse, mutect2
- NPDC1 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as rs374659308; called by muse, mutect2, varscan2
- NPEPL1 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.731); catalogued as rs761634929; called by muse, mutect2
- NPY5R | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.523); catalogued as rs80086880; called by muse, mutect2, varscan2
- NRBP2 | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as rs570469629, COSV100589211; called by muse, mutect2, varscan2
- NRP2 | c.2317G>A p.E773K | Missense Mutation (SNP) | VAF 180/472 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs762216772; called by mutect2, varscan2
- NT5DC1 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 59/205 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.501); catalogued as rs1048561362; called by muse, mutect2, varscan2
- NT5DC2 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 98/256 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs141804495; called by muse, mutect2, varscan2
- NUMBL | c.101C>T p.T34M | Missense Mutation (SNP) | VAF 49/219 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.517); catalogued as rs1164547461; called by muse, mutect2, varscan2
- NUP160 | c.3719C>T p.T1240M | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as rs535059681, COSV65854418; called by muse, mutect2, varscan2
- NUP210 | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 77/175 reads (44%) | catalogued as rs772458277; called by muse, mutect2, varscan2
- OBSCN | c.6961C>T p.R2321W | Missense Mutation (SNP) | VAF 102/244 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs371888438, COSV52766883; called by muse, mutect2, varscan2
- OBSCN | c.8690C>T p.T2897M | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.313); catalogued as rs542895771, COSV52748561; called by muse, mutect2, varscan2
- OCRL | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 101/216 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1305100597, COSV63980218; called by muse, mutect2, varscan2
- OGG1 | c.661G>A p.G221R | Missense Mutation (SNP) | VAF 168/512 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs373826669; called by muse, mutect2, varscan2
- OR4D10 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs759857725; called by muse, mutect2, varscan2
- OR4D5 | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 145/217 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs776996786, COSV58309069; called by muse, mutect2, varscan2
- OR51E1 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as rs200258520, COSV67809481; called by muse, mutect2, varscan2
- OR52E6 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.262); catalogued as rs748245396, COSV61431701, COSV61433472; called by muse, mutect2, varscan2
- OR5B12 | c.589_590del p.I197Ffs*8 | Frame Shift Del (DEL) | VAF 21/97 reads (22%) | catalogued as rs776684579; called by mutect2, pindel, varscan2
- OR5P2 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 56/161 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as rs770520472, COSV104412975; called by muse, mutect2, varscan2
- OR5T1 | c.302del p.N101Ifs*36 | Frame Shift Del (DEL) | VAF 20/149 reads (13%) | catalogued as rs780397839; called by mutect2, pindel, varscan2
- OSBP2 | c.1159C>T p.R387W | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs922992144, COSV60248354; called by muse, mutect2, varscan2
- OSM | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 59/123 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs750012343; called by muse, mutect2, varscan2
- P2RX4 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.667); catalogued as rs772182699, COSV61216679; called by muse, mutect2
- P2RY2 | c.124G>A p.V42M | Missense Mutation (SNP) | VAF 77/217 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs372504224; called by muse, mutect2, varscan2
- P4HA2 | c.1371C>T p.Y457= | Splice Region (SNP) | VAF 79/183 reads (43%) | catalogued as rs759732903, COSV99386765; called by muse, mutect2, varscan2
- PAN2 | c.151G>A p.V51I | Missense Mutation (SNP) | VAF 48/262 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.077); catalogued as rs774312153; called by muse, mutect2, varscan2
- PAPLN | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 72/175 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs930664832, COSV53721673; called by muse, mutect2, varscan2
- PAQR5 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 69/144 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760345131, COSV61818625; called by muse, mutect2, varscan2
- PARP3 | c.1576C>T p.R526C | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs201923901, COSV101290682; called by muse, mutect2, varscan2
- PARP4 | c.3064G>A p.G1022R | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748091610, COSV67963052; called by muse, mutect2, varscan2
- PATL1 | c.478dup p.Q160Pfs*6 | Frame Shift Ins (INS) | VAF 40/100 reads (40%) | catalogued as rs757903860; called by mutect2, varscan2
- PBRM1 | c.2932G>A p.V978I | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.057); catalogued as rs375687372; called by muse, mutect2, varscan2
- PCARE | c.3604C>T p.R1202* | Nonsense Mutation (SNP) | VAF 160/386 reads (41%) | catalogued as rs748396645, COSV59053218; called by muse, mutect2, varscan2
- PCDHA5 | c.1606G>A p.A536T | Missense Mutation (SNP) | VAF 286/634 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs781942385, COSV65350269; called by muse, varscan2
- PCDHA5 | c.1865G>A p.R622H | Missense Mutation (SNP) | VAF 145/301 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.052); catalogued as rs1326482790; called by muse, mutect2, varscan2
- PCDHA9 | c.2210C>T p.P737L | Missense Mutation (SNP) | VAF 133/273 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.533); catalogued as COSV65334243; called by muse, mutect2, varscan2
- PCDHB14 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 190/442 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.251); catalogued as rs777821767, COSV53386829, COSV99505975; called by mutect2, varscan2
- PCID2 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs999169767, COSV99872258; called by muse, mutect2, varscan2
- PCIF1 | c.590del p.P197Rfs*14 | Frame Shift Del (DEL) | VAF 64/269 reads (24%) | catalogued as COSV65026902; called by mutect2, pindel, varscan2
- PCNT | c.8210G>A p.R2737Q | Missense Mutation (SNP) | VAF 92/254 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs750074233; called by muse, mutect2, varscan2
- PDE2A | c.2716G>A p.G906S | Missense Mutation (SNP) | VAF 30/288 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV57815080; called by muse, varscan2
- PDE4DIP | c.2747G>A p.R916Q | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.932); catalogued as rs782389148, COSV57709569; called by muse, mutect2
- PDLIM2 | c.230G>A p.R77Q (on ENST00000397760; = p.R327Q on NM_021630.6) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.893); catalogued as rs773625739; called by muse, mutect2, varscan2
- PDP2 | c.1415C>T p.T472M | Missense Mutation (SNP) | VAF 82/194 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758673761, COSV61241574; called by muse, mutect2, varscan2
- PDZD4 | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.7); catalogued as rs1158677627; called by muse, mutect2, varscan2
- PER3 | c.3268G>A p.V1090I | Missense Mutation (SNP) | VAF 63/174 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV100728229; called by muse, mutect2, varscan2
- PGM2 | c.1718G>A p.C573Y | Missense Mutation (SNP) | VAF 80/161 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs1171377890; called by muse, mutect2, varscan2
- PGS1 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 71/196 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs763664131; called by muse, mutect2, varscan2
- PHF14 | c.2027G>A p.R676Q | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.14); catalogued as rs753298294, COSV68854007; called by muse, mutect2, varscan2
- PHF8 | c.2027G>A p.R676Q (on ENST00000357988 / NM_001184896.1; = p.R640Q on NM_015107.3) | Missense Mutation (SNP) | VAF 85/253 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.157); catalogued as rs782604120, COSV100153933, COSV57686975; called by muse, mutect2, varscan2
- PHLDB2 | c.3704G>A p.R1235Q (on ENST00000393925 / NM_001134439.2; = p.R1192Q on NM_145753.2) | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs765003590; called by muse, mutect2, varscan2
- PHYKPL | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 77/153 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.05); catalogued as rs765616846; called by muse, mutect2, varscan2
- PI16 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 100/237 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs753312563, COSV101028844; called by muse, mutect2, varscan2
- PIK3R3 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 57/181 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs746011332, COSV53107616; called by muse, mutect2, varscan2
- PIK3R4 | c.3140C>T p.T1047M | Missense Mutation (SNP) | VAF 69/169 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.769); catalogued as rs749751291, COSV100768255; called by muse, mutect2, varscan2
- PINK1 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 115/445 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs1464230596, COSV58631096; called by muse, mutect2, varscan2
- PITPNM3 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 189/446 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1387762572, COSV52600078; called by muse, mutect2, varscan2
- PKHD1L1 | c.624-2A>C p.X208_splice | Splice Site (SNP) | VAF 22/76 reads (29%) | catalogued as COSV101006193; called by muse, varscan2
- PKN1 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.105); catalogued as COSV54398857, COSV54404264; called by muse, mutect2
- PKN1 | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs940131082; called by muse, mutect2, varscan2
- PKNOX1 | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 70/234 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs757747006, COSV52338715; called by muse, mutect2, varscan2
- PLA1A | c.511G>A p.V171I | Missense Mutation (SNP) | VAF 71/192 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.662); catalogued as rs762609611, COSV56331250; called by muse, varscan2
- PLCD4 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.76); PolyPhen benign (0.034); catalogued as rs753062524; called by mutect2, varscan2
- PLCG1 | c.2120G>A p.R707Q | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54814695; called by muse, mutect2, varscan2
- PLCH2 | c.3499C>T p.R1167C | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs371812903, COSV53946518; called by muse, mutect2
- PLEC | c.12533G>A p.R4178H (on ENST00000322810 / NM_201380.4; = p.R4068H on NM_000445.5) | Missense Mutation (SNP) | VAF 107/280 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs370636109; called by muse, mutect2, varscan2
- PLEC | c.2035G>A p.A679T (on ENST00000322810 / NM_201380.4; = p.A569T on NM_000445.5) | Missense Mutation (SNP) | VAF 115/249 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as rs369715210, COSV100512479; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEK2 | c.70C>T p.R24* | Nonsense Mutation (SNP) | VAF 34/72 reads (47%) | catalogued as rs764876253; called by muse, mutect2, varscan2
- PLEKHM1 | c.1627C>T p.R543W | Missense Mutation (SNP) | VAF 323/785 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1278142171, COSV101378720; called by muse, mutect2, varscan2
- PLEKHM2 | c.1562C>T p.T521M | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs201504895; called by muse, mutect2, varscan2
- PLEKHM2 | c.1751C>T p.S584L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as rs755008863, COSV101009177; called by muse, mutect2, varscan2
- PLOD2 | c.1991G>A p.R664H | Missense Mutation (SNP) | VAF 34/243 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs144675042; called by muse, mutect2, varscan2
- PLPP3 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150738833; called by muse, mutect2, varscan2
- PLXNA2 | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 92/212 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748090782; called by muse, mutect2, varscan2
- PLXNA4 | c.4127G>A p.R1376H | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs750458788, COSV58102490; called by muse, mutect2, varscan2
- PMM1 | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 180/237 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs768275464; called by muse, mutect2, varscan2
- PNKD | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 88/242 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs777574834, COSV51231307, COSV99282122; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PNMT | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 82/207 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.519); catalogued as rs202144149; called by muse, mutect2, varscan2
- POLB | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs766919977, COSV55183675; called by muse, mutect2, varscan2
- POLR2A | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as rs777312684, COSV59492390; called by muse, mutect2, varscan2
- POM121L2 | c.2015C>T p.A672V | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.093); catalogued as rs1027810507; called by muse, mutect2, varscan2
- POMGNT2 | c.218C>T p.T73M | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs765805874, COSV100768066; called by muse, mutect2, varscan2
- POP4 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 87/270 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs774977285; called by muse, mutect2, varscan2
- POU5F2 | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs1561435028, COSV67941766; called by muse, mutect2, varscan2
- POU6F2 | c.1763G>A p.R588H | Missense Mutation (SNP) | VAF 107/452 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs560129989; called by muse, mutect2, varscan2
- PPARGC1B | c.2107G>A p.V703I | Missense Mutation (SNP) | VAF 111/359 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs115650813, COSV58533468; called by muse, mutect2, varscan2
- PPFIA3 | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV61953557; called by muse, mutect2, varscan2
- PPL | c.3607C>T p.R1203W | Missense Mutation (SNP) | VAF 127/308 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs753167986, COSV52167039; called by muse, mutect2, varscan2
- PPP1R35 | c.436_438del p.E146del | In Frame Del (DEL) | VAF 66/233 reads (28%) | catalogued as rs768983019; called by pindel, varscan2
- PPP2R2C | c.541G>A p.V181I | Missense Mutation (SNP) | VAF 95/199 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs373814468; called by muse, mutect2, varscan2
- PPP2R5E | c.236C>T p.T79M | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs781401535; called by muse, mutect2
- PPP6R1 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 86/318 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs1045165828; called by muse, mutect2, varscan2
- PRAMEF27 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 88/449 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1174375626; called by muse, mutect2, varscan2
- PRIMPOL | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as rs141036465; called by muse, mutect2, varscan2
- PRKACG | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 152/403 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as rs866122115; called by muse, mutect2, varscan2
- PRKAR1B | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 60/223 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs759197351; called by muse, mutect2, varscan2
- PRKAR1B | c.260dup p.N88Efs*56 | Frame Shift Ins (INS) | VAF 19/133 reads (14%) | catalogued as rs764069617; called by mutect2, varscan2
- PRMT2 | c.70G>A p.G24S | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs904593804, COSV52457072; called by muse, mutect2
- PRPF39 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 105/276 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs1446550982, COSV99361234; called by muse, mutect2, varscan2
- PRR12 | c.1439C>T p.A480V (on ENST00000615927; = p.A1301V on NM_020719.3) | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs779126530, COSV69818984; called by muse, mutect2, varscan2
- PRR23A | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 107/284 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.893); catalogued as COSV101270269; called by muse, mutect2, varscan2
- PRRC2B | c.1198G>A p.G400S | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as rs184776247, COSV100621502; called by muse, mutect2, varscan2
- PRRC2B | c.5860G>A p.A1954T | Missense Mutation (SNP) | VAF 96/272 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs756979652, COSV100261166; called by muse, mutect2, varscan2
- PRSS3 | c.43G>A p.V15M (on ENST00000361005 / NM_007343.4; = p.V123M on NM_002771.3) | Missense Mutation (SNP) | VAF 146/660 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs760064088, COSV61555856; called by muse, varscan2
- PRSS57 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.041); catalogued as rs774386363; called by muse, mutect2, varscan2
- PSG6 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 69/225 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.089); catalogued as COSV51835139; called by muse, mutect2, varscan2
- PSG7 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 103/410 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs573042386; called by muse, mutect2, varscan2
- PSMA8 | c.150del p.K50Nfs*12 | Frame Shift Del (DEL) | VAF 28/134 reads (21%) | catalogued as rs749240094; called by mutect2, varscan2
- PSMA8 | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 59/118 reads (50%) | catalogued as rs749936851, COSV100379168; called by muse, mutect2, varscan2
- PSMD7 | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.243); catalogued as rs767429948; called by muse, mutect2
- PSME3 | c.404C>T p.T135M | Missense Mutation (SNP) | VAF 86/182 reads (47%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.95); catalogued as rs767374760, COSV99513633; called by muse, varscan2
- PTGDS | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs750503509; called by muse, mutect2, varscan2
- PTGS1 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 178/453 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as rs1273597287, COSV56289953; called by muse, mutect2, varscan2
- PTK6 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs764440367; called by muse, mutect2
- PTPRD | c.2080G>A p.G694S | Missense Mutation (SNP) | VAF 140/215 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1413041664; called by muse, mutect2, varscan2
- PTPRN | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 94/195 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs139530025; called by muse, mutect2, varscan2
- PXDNL | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 70/169 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.781); catalogued as rs773020985; called by muse, mutect2, varscan2
- PXMP4 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 136/450 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1401777003, COSV54134056; called by muse, mutect2, varscan2
- PYGB | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1438151389, COSV53820968; called by muse, mutect2, varscan2
- PYROXD2 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT deleterious (0.03); PolyPhen benign (0.177); catalogued as rs544916988; called by muse, mutect2, varscan2
- QTRT2 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 91/214 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs376673299; called by muse, mutect2, varscan2
- R3HDM2 | c.2914C>T p.R972* | Nonsense Mutation (SNP) | VAF 3/22 reads (14%) | catalogued as rs999400739; called by muse, mutect2
- RAB25 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.213); catalogued as rs1420810222; called by muse, mutect2
- RAB35 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 66/206 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as rs748118400; called by muse, mutect2, varscan2
- RAB3A | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 57/197 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55851916; called by muse, mutect2, varscan2
- RABL2B | c.418G>A p.V140M | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.529); catalogued as rs782069543, COSV61483336; called by muse, mutect2, varscan2
- RAC1 | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 12/105 reads (11%) | catalogued as COSV100641009; called by muse, mutect2, varscan2
- RAI14 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780343550; called by muse, mutect2, varscan2
- RARS2 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 179/487 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as rs747644029; called by muse, mutect2, varscan2
- RBM14 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 7/169 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59557570; called by muse, mutect2
- RBM39 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 97/425 reads (23%) | catalogued as rs1265088399, COSV99488536; called by muse, mutect2, varscan2
- RBM47 | c.1484C>T p.A495V (on ENST00000295971 / NM_001098634.2; = p.A426V on NM_019027.4) | Missense Mutation (SNP) | VAF 172/313 reads (55%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs938475554; called by muse, mutect2, varscan2
- RBM47 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 28/373 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.34); catalogued as rs1423625557; called by muse, mutect2
- RC3H1 | c.1355G>A p.R452H | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs768398038; called by muse, mutect2, varscan2
- RCN3 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs774822949, COSV54543808; called by muse, mutect2, varscan2
- RECQL5 | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 68/189 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs778479063, COSV58641318; called by muse, mutect2, varscan2
- REEP6 | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 80/360 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747486549; called by muse, mutect2, varscan2
- REG3A | c.452G>T p.R151I | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.226); catalogued as COSV59410325; called by muse, mutect2, varscan2
- RELCH | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as COSV56885392; called by muse, mutect2, varscan2
- REM1 | c.767del p.P256Qfs*9 | Frame Shift Del (DEL) | VAF 38/446 reads (9%) | catalogued as rs1295418059, COSV99146775; called by mutect2, pindel
- REXO1 | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs774754913, COSV99401970; called by muse, mutect2, varscan2
- RFXANK | c.438+4C>T | Splice Region (SNP) | VAF 96/319 reads (30%) | catalogued as rs749058206; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RFXANK | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 147/534 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs749859039, COSV100284425; called by muse, mutect2, varscan2
- RHOXF1 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0.285); catalogued as rs782174738, COSV54295078; called by muse, mutect2, varscan2
- RIMS3 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 142/350 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as rs768755559, COSV101013262; called by muse, mutect2, varscan2
- RING1 | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.527); catalogued as rs749950359; called by muse, mutect2
- RMDN3 | c.379C>T p.R127* | Nonsense Mutation (SNP) | VAF 26/63 reads (41%) | catalogued as rs756219717; called by muse, mutect2, varscan2
- RNF212 | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 100/226 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs760580889; called by muse, mutect2, varscan2
- RNF213 | c.12859C>T p.R4287W | Missense Mutation (SNP) | VAF 91/231 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as rs994498410, COSV60404254; called by muse, mutect2, varscan2
- RNF216 | c.2486C>T p.P829L (on ENST00000425013 / NM_207116.3; = p.P886L on NM_207111.4) | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs868768655; called by muse, mutect2, varscan2
- ROS1 | c.5743G>A p.G1915R | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.383); catalogued as rs759091073, COSV63861219; called by muse, mutect2, varscan2
- RPGRIP1 | c.2099G>A p.R700Q | Missense Mutation (SNP) | VAF 109/272 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.081); catalogued as rs768190736, COSV52855578; called by muse, mutect2, varscan2
- RPL10L | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 111/240 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as rs1313205670, COSV100022411; called by muse, mutect2, varscan2
- RPL10L | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 84/221 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.114); catalogued as rs181539648, COSV53559725, COSV53560421; called by muse, mutect2, varscan2
- RPRD2 | c.4097G>A p.R1366Q | Missense Mutation (SNP) | VAF 64/203 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as rs200636649; called by muse, mutect2, varscan2
- RPS5 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 52/230 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs769796504; called by muse, mutect2, varscan2
- RPS6KB1 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.738); catalogued as rs1181565268; called by muse, mutect2, varscan2
- RSAD1 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765840119; called by muse, mutect2, varscan2
- RTL9 | c.2933C>T p.P978L | Missense Mutation (SNP) | VAF 64/155 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.938); catalogued as rs146399635, COSV71825450; called by muse, mutect2, varscan2
- RXRA | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs748518062, COSV62685206; called by muse, mutect2, varscan2
- RYR1 | c.3124G>A p.V1042M | Missense Mutation (SNP) | VAF 78/299 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs540088339; called by muse, mutect2, varscan2
- RYR1 | c.11518G>A p.V3840I | Missense Mutation (SNP) | VAF 171/589 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs140616359, CM064223; ClinVar: benign / uncertain significance / not provided; called by muse, mutect2, varscan2
- RYR2 | c.4754G>A p.R1585H | Missense Mutation (SNP) | VAF 85/203 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1392451418, COSV63661428; called by muse, mutect2, varscan2
- RYR3 | c.4700C>T p.A1567V | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs375544562, COSV66812458; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAAL1 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1222499873; called by muse, mutect2, varscan2
- SALL4 | c.2983del p.V995Ffs*14 | Frame Shift Del (DEL) | VAF 195/678 reads (29%) | catalogued as rs753320334; called by mutect2, varscan2
- SAMD9L | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 75/293 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as rs141294380; called by muse, mutect2, varscan2
1,123 further variants in this file (443 protein-altering or splice-affecting, 479 silent, 201 other) are not listed here.
